Somatic mutation profile of tumor specimen TCGA-A5-A2K3-01A (aliquot TCGA-A5-A2K3-01A-11D-A17W-09) from TCGA case TCGA-A5-A2K3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 68.2 years (24,907 days).
Specimen TCGA-A5-A2K3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e334142e-a0f6-4bae-91ee-0af09f24ec7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A2K3-10A (Blood Derived Normal), aliquot TCGA-A5-A2K3-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/365c5e11-a349-4151-b2d4-9a37f9ee1352

The open-access MAF lists 1,430 somatic variants for this specimen: 1,020 protein-altering or splice-affecting, 379 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 880, Silent 379, Nonsense Mutation 54, Frame Shift Del 47, Splice Site 18, Intron 14, Frame Shift Ins 10, Splice Region 8, RNA 7, 3'UTR 5, 5'Flank 3, 3'Flank 2.

Variants (750 of 1,430; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPM | c.9910C>T p.R3304* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs587783295, CM142028, COSV54134088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAX | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs398122513, COSV53170407; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A2 | c.1776+1G>A p.X592_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as rs886039602, COSV64630141; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- GABRA1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs727503940, COSV50119921, COSV99195708; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as rs1057520291, CM093342, CM971451, COSV57458707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16052G>A p.R5351Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1555185217, CM138443, COSV56409652, COSV56494348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MFRP | c.487C>T p.R163C (on ENST00000449574; = p.R539C on NM_031433.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374823079, CM155304; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3013C>T p.R1005* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs63750563, CM053329, COSV99315067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MTHFR | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769953411, COSV64878141; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5854C>T p.R1952W | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886041219, CM052316, COSV61771898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1810T>C p.C604R | Missense Mutation (SNP) | VAF 25/99 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV55888333; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 9/108 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2
- VPS13B | c.5086C>T p.R1696* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs386834093, CM110615, COSV62153546; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs775713265, COSV52628454; called by muse, mutect2, varscan2
- AAAS | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777711720, COSV99266809; called by muse, mutect2, varscan2
- AASDH | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99220801; called by muse, mutect2, varscan2
- ABCA2 | c.371C>T p.T124M (on ENST00000614293; = p.T94M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs527726916, COSV99686895; called by mutect2, varscan2
- ABCA7 | c.3268C>T p.R1090W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs757408547, COSV99565160; called by muse, mutect2, varscan2
- ABCB1 | c.3337C>A p.L1113M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.293); catalogued as COSV99712083, COSV99712164; called by muse, mutect2, varscan2
- ABCC11 | c.3631C>A p.L1211M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100750530; called by muse, mutect2
- ABCC6 | c.3686G>A p.S1229N | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs940876455, COSV99228062; called by muse, mutect2, varscan2
- ABHD11 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99766659; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs773804575, COSV99865262; called by muse, mutect2, varscan2
- ABHD15 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as rs150059487, COSV56194898; called by muse, mutect2, varscan2
- ABT1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs782814898, COSV51290936; called by muse, mutect2, varscan2
- AC011455.2 | c.1093A>G p.N365D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.792); catalogued as COSV99671110; called by muse, mutect2, varscan2
- AC092143.1 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs587784505, CM161052, COSV100205598; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACACB | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1207186713, COSV58139713; called by muse, mutect2, varscan2
- ACAD10 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768303210, COSV100563816; called by muse, mutect2, varscan2
- ACIN1 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV52980981; called by muse, mutect2, varscan2
- ACLY | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375650392; called by muse, mutect2, varscan2
- ACSL3 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100657860; called by muse, mutect2
- ACSM3 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs756159393, COSV99184047; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD2 | c.515C>T p.A172V (on ENST00000315906 / NM_001145400.2; = p.A244V on NM_139174.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs756625312, COSV99235079; called by muse, mutect2, varscan2
- ADAMTS20 | c.2355del p.E786Kfs*86 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs1177283960; called by mutect2, pindel, varscan2
- ADAMTS6 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868253589, COSV100068251; called by muse, mutect2, varscan2
- ADAMTS7 | c.3227T>C p.L1076P | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101183010; called by muse, mutect2
- ADAMTSL1 | c.1650G>T p.Q550H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99440960; called by muse, mutect2
- ADARB2 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201838719, COSV67182577; called by muse, mutect2, varscan2
- ADAT1 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.218); catalogued as COSV100329099; called by muse, mutect2, varscan2
- ADCY7 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as rs950416731, COSV54267609; called by muse, mutect2, varscan2
- ADD3 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99523182; called by muse, mutect2, varscan2
- ADGRA3 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV51568135; called by muse, mutect2, varscan2
- ADGRL1 | c.3736G>A p.G1246S (on ENST00000340736 / NM_001008701.3; = p.G1241S on NM_014921.5) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100529260; called by muse, mutect2, varscan2
- ADRA2A | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99701462; called by muse, mutect2
- AFDN | c.4904G>A p.R1635Q (on ENST00000447894 / NM_001366320.1; = p.R1633Q on NM_001040000.3) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.435); catalogued as rs1298622308, COSV100652458; called by muse, mutect2
- AGPAT3 | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | catalogued as COSV99377141; called by muse, mutect2, varscan2
- AHCYL2 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61488888; called by muse, mutect2, varscan2
- AHNAK | c.10868A>G p.D3623G | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99945587; called by muse, mutect2, varscan2
- AHNAK2 | c.11305G>A p.V3769M | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs199717476, COSV60920747; called by muse, mutect2, varscan2
- AKAP9 | c.6752A>G p.Q2251R (on ENST00000359028; = p.Q2227R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV100661913; called by muse, mutect2, varscan2
- AKR1B1 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99605155; called by muse, mutect2, varscan2
- ALOX12B | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144923268; called by muse, mutect2, varscan2
- ALPK2 | c.5878A>G p.I1960V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100864116; called by muse, mutect2
- ALPP | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.034); catalogued as COSV101235085; called by muse, varscan2
- AMOTL1 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as rs757885859, COSV100504203; called by muse, mutect2, varscan2
- AMPD3 | c.961G>A p.A321T (on ENST00000396553 / NM_001025389.2; = p.A330T on NM_000480.3) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101158085; called by muse, mutect2, varscan2
- AMPH | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs772069356, COSV100340911, COSV57747907; called by muse, mutect2, varscan2
- ANGEL2 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as rs982573649, COSV64737165, COSV64737255; called by muse, mutect2, varscan2
- ANGPTL7 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100815720; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99782077; called by muse, mutect2, varscan2
- ANKIB1 | c.1211A>G p.Y404C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99728359; called by muse, mutect2
- ANKIB1 | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1361399149, COSV99728363; called by muse, mutect2, varscan2
- ANKLE2 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100513929, COSV100514177; called by muse, mutect2, varscan2
- ANKRD10 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.999); catalogued as COSV99941032; called by muse, mutect2, varscan2
- ANKRD13B | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as rs1405395467, COSV67474322; called by muse, mutect2, varscan2
- ANKRD17 | c.1525C>T p.R509* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV58223986; called by muse, mutect2, varscan2
- ANKRD24 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99516954; called by muse, mutect2, varscan2
- ANKRD26 | c.1110del p.E371Kfs*12 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as rs775948884, COSV65797837; called by mutect2, pindel, varscan2
- AP3M1 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100786644; called by muse, mutect2, varscan2
- APBB2 | c.1514G>A p.R505H (on ENST00000295974 / NM_001166050.2; = p.R506H on NM_004307.2) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs959299569, COSV99922449; called by muse, mutect2, varscan2
- ARF1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.071); catalogued as COSV55255004; called by muse, mutect2, varscan2
- ARFGEF1 | c.5195G>A p.R1732H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51602818; called by muse, mutect2, varscan2
- ARHGAP11A | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); catalogued as rs570927659, COSV100853155; called by mutect2, varscan2
- ARHGAP26 | c.1898G>A p.S633N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV50836713; called by muse, mutect2, varscan2
- ARHGAP33 | c.2726G>T p.R909M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99137585; called by muse, mutect2
- ARHGAP35 | c.3433C>T p.R1145* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV68329138; called by muse, mutect2, varscan2
- ARHGAP44 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762885019, COSV99310087; called by muse, mutect2, varscan2
- ARHGEF1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs782691132, COSV100528843; called by muse, mutect2
- ARHGEF10 | c.406G>A p.A136T (on ENST00000398564; = p.A112T on NM_014629.4) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs751134443, COSV100033801; called by muse, mutect2
- ARHGEF15 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100729978; called by muse, mutect2
- ARHGEF17 | c.5143C>T p.R1715C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139686329; called by muse, varscan2
- ARHGEF18 | c.1492A>G p.I498V (on ENST00000359920 / NM_001130955.2; = p.I394V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100148957; called by mutect2, varscan2
- ARHGEF2 | c.416G>A p.R139H (on ENST00000361247 / NM_001162383.2; = p.R112H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs374781823; called by muse, mutect2, varscan2
- ARID1A | c.1991C>A p.S664* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100250329, COSV61383603; called by muse, mutect2, varscan2
- ARL8A | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1483120919, COSV99693196; called by muse, mutect2, varscan2
- ARMC10 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as COSV100085630; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs369432744, COSV100771865, COSV63438046; called by muse, mutect2, varscan2
- ARNTL2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs952743145, COSV53826207; called by muse, mutect2, varscan2
- ARPC4 | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV99809326; called by muse, mutect2
- ARRB2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.926); catalogued as COSV52617137; called by muse, mutect2, varscan2
- ARVCF | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1385413426, COSV99258289; called by muse, mutect2, varscan2
- ASB2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs141584945; called by muse, mutect2, varscan2
- ASH1L | c.8227C>T p.R2743W (on ENST00000368346 / NM_001366177.2; = p.R2738W on NM_018489.3) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64213590; called by muse, mutect2, varscan2
- ASIC2 | c.1437+1G>A p.X479_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99859306; called by muse, mutect2, varscan2
- ATAD3B | c.545C>T p.T182M (on ENST00000308647; = p.T288M on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs746903013, COSV100426284; called by muse, mutect2, varscan2
- ATN1 | c.1889C>T p.T630M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV100755667; called by muse, mutect2, varscan2
- ATP13A2 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs781304413, COSV58701746; called by muse, mutect2, varscan2
- ATP2B1 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as COSV53806414; called by muse, mutect2, varscan2
- ATP4A | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as rs749245477, COSV52867112; called by muse, mutect2, varscan2
- ATP8B2 | c.2248C>T p.R750W (on ENST00000672630; = p.R717W on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs375666727; called by muse, mutect2, varscan2
- ATP8B4 | c.2289+2T>C p.X763_splice | Splice Site (SNP) | VAF 7/69 reads (10%) | catalogued as COSV99463733; called by muse, mutect2, varscan2
- ATPAF2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.063); catalogued as rs777247426, COSV71398542; called by muse, mutect2, varscan2
- ATXN1 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); catalogued as rs770389558, COSV99785027; called by muse, mutect2, varscan2
- AVIL | c.1322A>G p.Y441C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168269017, COSV99142163; called by muse, mutect2, varscan2
- B3GALNT2 | c.1076G>A p.C359Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs1553342979, COSV100782748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GAT3 | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as COSV99605698; called by muse, mutect2, varscan2
- B4GALNT4 | c.2920T>G p.F974V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV100327190; called by muse, mutect2, varscan2
- BAHCC1 | c.4631G>T p.S1544I | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs782027842, COSV100311171; called by muse, mutect2, varscan2
- BARX2 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769021373, COSV55650354; called by muse, mutect2, varscan2
- BCAR1 | c.2288A>G p.D763G | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99365983; called by mutect2, varscan2
- BCL2L2 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355053032, COSV99161455; called by muse, mutect2, varscan2
- BICD1 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV99861974; called by muse, mutect2, varscan2
- BLMH | c.67dup p.Q23Pfs*71 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | catalogued as rs748478324; called by mutect2, pindel
- BMP7 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67780993; called by muse, mutect2, varscan2
- BOP1 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs890162857; called by muse, mutect2, varscan2
- BRAT1 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs371239207, COSV100500339; called by muse, mutect2, varscan2
- BRCA2 | c.5794C>T p.H1932Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV101203930; called by muse, mutect2, varscan2
- BRF1 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs771169144, COSV100526822; called by muse, mutect2, varscan2
- BRINP2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777970525, COSV100837833; called by muse, mutect2, varscan2
- BSG | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100344486; called by muse, mutect2, varscan2
- BSN | c.6470G>A p.G2157D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs773770206, COSV99607287; called by mutect2, varscan2
- BSN | c.9493G>A p.A3165T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs748425735, COSV99607293; called by muse, mutect2, varscan2
- BTC | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV101201467; called by muse, mutect2, varscan2
- BUD23 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372476415; called by muse, mutect2, varscan2
- C10orf90 | c.764G>T p.R255M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99503097, COSV99503141; called by muse, mutect2, varscan2
- C14orf180 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.682); catalogued as rs533313972, COSV100118702; called by muse, mutect2
- C2CD3 | c.3500T>C p.L1167S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); catalogued as COSV100486250; called by muse, mutect2
- C2CD6 | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV99631920; called by muse, mutect2, varscan2
- C3orf38 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59627813; called by muse, mutect2, varscan2
- C6 | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV99666512; called by muse, mutect2, varscan2
- C6orf118 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.034); catalogued as rs917334465, COSV57814416, COSV57818972; called by mutect2, varscan2
- C8A | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as rs775054168, COSV63485447; called by muse, mutect2, varscan2
- C9 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs758936981, COSV54674236; called by muse, mutect2, varscan2
- C9orf50 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750800254, COSV65252884; called by muse, mutect2, varscan2
- CA5A | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs142182110; called by muse, mutect2, varscan2
- CACNA1D | c.5312G>A p.R1771Q (on ENST00000350061 / NM_001128840.3; = p.R1791Q on NM_000720.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs776723045, COSV99856607, COSV99856699; called by muse, mutect2, varscan2
- CACNA1E | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62399794; called by muse, mutect2
- CACNA1H | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748013647, COSV62003583; called by muse, mutect2, varscan2
- CACNA1H | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs745597129, COSV100670845; called by muse, mutect2, varscan2
- CACNA2D3 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99870405; called by muse, mutect2, varscan2
- CACNA2D4 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs761969045, COSV54955872; called by muse, mutect2, varscan2
- CAD | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs761369810, COSV99254420; called by muse, mutect2, varscan2
- CADM4 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs770581423, COSV99731307; called by muse, mutect2, varscan2
- CAPN11 | c.191A>T p.Q64L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101291841; called by muse, mutect2, varscan2
- CAPN9 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200358258, COSV55235150; called by muse, mutect2, varscan2
- CARHSP1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs201523233, COSV100220146, COSV60683801; called by muse, mutect2, varscan2
- CARMIL3 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs757377104, COSV53742395; called by muse, mutect2, varscan2
- CATSPERG | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs1267190870, COSV53053041; called by muse, mutect2, varscan2
- CAVIN1 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100824501; called by muse, mutect2, varscan2
- CCDC102A | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs138430955; called by mutect2, varscan2
- CCDC144A | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV100501939, COSV61403545; called by muse, mutect2, varscan2
- CCDC17 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749615206, COSV59648967; called by muse, mutect2, varscan2
- CCDC178 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100283401; called by muse, mutect2, varscan2
- CCDC32 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100785897, COSV63635302; called by muse, mutect2, varscan2
- CCDC62 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as rs868358982, COSV99456513; called by muse, mutect2, varscan2
- CCDC8 | c.829C>A p.R277S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.133); catalogued as rs370524521, COSV100281876, COSV56774340; called by muse, mutect2, varscan2
- CD163L1 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1178461672, COSV100549672; called by muse, mutect2, varscan2
- CD248 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.919); catalogued as rs539641105, COSV60935987; called by mutect2, varscan2
- CD40LG | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV101033423; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDCA7L | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100177142; called by muse, mutect2
- CDH15 | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV99228038; called by muse, mutect2, varscan2
- CDH23 | c.913C>A p.L305M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as rs1038347646, CD1413490, COSV99818862; called by muse, mutect2, varscan2
- CDH23 | c.2911G>T p.G971C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99818867; called by muse, mutect2, varscan2
- CDH23 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs747839724, COSV54930498; called by muse, mutect2, varscan2
- CDH23 | c.8042G>A p.R2681H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1211837259, COSV99034549; called by muse, mutect2
- CDH7 | c.1972G>A p.G658R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs116566190, COSV59882861, COSV59896451; called by muse, mutect2, varscan2
- CDHR1 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143024855, COSV60567112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK19 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs781628403, COSV60447327; called by mutect2, varscan2
- CDKL5 | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs1354788122, COSV66112857; called by muse, mutect2, varscan2
- CDR1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs761193821, COSV65163870; called by muse, mutect2, varscan2
- CELSR1 | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs773813117, COSV53100290; called by muse, mutect2, varscan2
- CELSR1 | c.3922C>A p.L1308M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99416832; called by muse, mutect2, varscan2
- CEP192 | c.4263T>A p.D1421E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100380577; called by muse, mutect2, varscan2
- CEP192 | c.5665G>A p.V1889I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs768565025, COSV58063273; called by mutect2, varscan2
- CEP85L | c.2070G>T p.Q690H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100874053; called by muse, mutect2, varscan2
- CEP95 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs782594800; called by muse, mutect2
- CFAP157 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs763991791, COSV100076700; called by muse, mutect2, varscan2
- CFAP44 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.243); catalogued as COSV99868904; called by muse, mutect2, varscan2
- CFAP47 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs1569199135, COSV52889890, COSV99934401; called by muse, mutect2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs778664468; called by pindel, varscan2
- CFAP65 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV58563085; called by muse, varscan2
- CFAP65 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1291820068, COSV99838229; called by muse, mutect2, varscan2
- CHD3 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100390704; called by muse, mutect2, varscan2
- CHD4 | c.3275G>A p.R1092Q (on ENST00000357008 / NM_001363606.2; = p.R1105Q on NM_001273.5) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100537532, COSV100537818, COSV58899203; called by muse, mutect2, varscan2
- CHMP1A | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99498250; called by muse, mutect2, varscan2
- CHPF2 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99222775; called by muse, mutect2
- CHRM1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs745852921, COSV100186089, COSV61007277; called by muse, mutect2, varscan2
- CHST1 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV100345973; called by muse, mutect2, varscan2
- CHTF18 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs565099873, COSV50102458; called by muse, mutect2, varscan2
- CHTF18 | c.2325C>T p.P775= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as rs183561737, COSV50211116; called by muse, mutect2, varscan2
- CLASRP | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs935094801, COSV99673525; called by muse, mutect2
- CLCN3 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs981035966, COSV61629112; called by muse, mutect2, varscan2
- CLIP1 | c.2855G>A p.R952H (on ENST00000620786 / NM_001247997.1; = p.R941H on NM_002956.2) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs373246411, COSV100211211; called by muse, mutect2, varscan2
- CLIP1 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1320593798, COSV100211213; called by muse, mutect2
- CLIP3 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859216; called by muse, mutect2, varscan2
- CLPTM1 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372059273; called by muse, mutect2, varscan2
- CMTR2 | c.1937C>A p.P646H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57603399; called by muse, mutect2, varscan2
- CNKSR2 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1283129014, COSV99667367; called by muse, mutect2, varscan2
- CNNM4 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100998596; called by muse, mutect2, varscan2
- CNNM4 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs750374054, COSV65661152; ClinVar: uncertain significance; called by mutect2, varscan2
- CNOT3 | c.837G>A p.T279= | Splice Region (SNP) | VAF 7/47 reads (15%) | catalogued as COSV55361545, COSV99651449; called by muse, mutect2, varscan2
- CNP | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.477); catalogued as rs998291648, COSV57268700; called by mutect2, varscan2
- CNTD1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1339765228, COSV99889438; called by muse, mutect2, varscan2
- CNTN5 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV99672967; called by muse, mutect2, varscan2
- CNTNAP3 | c.3742G>A p.G1248R | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780222742; called by muse, mutect2
- CNTNAP5 | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs969802074, COSV101443060, COSV70502340; called by muse, mutect2
- CNTROB | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs905933564, COSV100972597; called by muse, mutect2
- COBLL1 | c.2751T>A p.N917K (on ENST00000392717; = p.N879K on NM_014900.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99527342; called by muse, mutect2
- COG1 | c.2501C>T p.P834L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55428327, COSV55429347; called by muse, mutect2, varscan2
- COL25A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960016417, COSV67651331; called by muse, mutect2, varscan2
- COL27A1 | c.5500C>T p.P1834S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100620731; called by muse, mutect2, varscan2
- COL5A1 | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV100879508; called by muse, mutect2
- COL5A1 | c.1569+1G>A p.X523_splice | Splice Site (SNP) | VAF 14/94 reads (15%) | catalogued as COSV65668094, COSV65674250; called by muse, mutect2, varscan2
- COL5A2 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.818); catalogued as rs762902468, COSV66407684; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- COL6A2 | c.608A>G p.D203G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs771962457, COSV100152981; called by muse, mutect2, varscan2
- COL6A6 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs771893072, COSV100649803, COSV62029954; called by mutect2, varscan2
- COPB2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100300470; called by muse, mutect2, varscan2
- CORT | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.539); catalogued as COSV100259153; called by muse, mutect2, varscan2
- COX20 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834628; called by muse, mutect2, varscan2
- CPA4 | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV55985890; called by muse, mutect2, varscan2
- CPNE6 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs143361499; called by muse, mutect2, varscan2
- CRAMP1 | c.3197G>A p.R1066Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.902); catalogued as rs776947246, COSV99245618; called by muse, mutect2, varscan2
- CREB3L2 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100381595; called by muse, mutect2, varscan2
- CTBP2 | c.1049C>G p.P350R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100456124, COSV100457072; called by muse, mutect2, varscan2
- CTIF | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99836838; called by muse, mutect2, varscan2
- CTPS2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV63721427, COSV63721758; called by muse, mutect2
- CUBN | c.5433C>A p.Y1811* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100912057; called by muse, mutect2, varscan2
- CUL7 | c.733-2A>G p.X245_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99537898; called by muse, mutect2, varscan2
- CUX1 | c.3983G>A p.R1328Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1235657318, COSV99470464; called by muse, mutect2
- CYB561D1 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as rs576030109, COSV60204674; called by muse, mutect2, varscan2
- CYP11A1 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368047178; called by muse, mutect2, varscan2
- CYP21A2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV100925826; called by muse, mutect2, varscan2
- CYP2A7 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs375415174; called by muse, mutect2, varscan2
- CYSLTR2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs148425155; called by muse, mutect2, varscan2
- DAAM1 | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100658148; called by muse, mutect2, varscan2
- DACT1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs755263046, COSV60019157; called by muse, mutect2, varscan2
- DARS2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150167473; called by muse, mutect2, varscan2
- DCDC2 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as rs746503285, COSV65833613; called by muse, mutect2, varscan2
- DCTN3 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV52406879; called by muse, mutect2, varscan2
- DDAH2 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs150096378; called by muse, mutect2, varscan2
- DEF6 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV100359155, COSV99079508; called by muse, mutect2, varscan2
- DEPDC5 | c.2294G>A p.R765Q (on ENST00000400246; = p.R834Q on NM_014662.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.83); catalogued as rs756611357, COSV56698612; called by muse, mutect2, varscan2
- DGCR6L | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99956792; called by muse, mutect2, varscan2
- DHRS4 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166230032, COSV100365753; called by muse, mutect2, varscan2
- DHRS7 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs1440824126, COSV99381481; called by muse, mutect2
- DHRS7B | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100683855; called by muse, mutect2
- DHX33 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as rs144497363; called by muse, mutect2, varscan2
- DIP2C | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as rs752906155, COSV55166314; called by mutect2, varscan2
- DIRAS1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as rs1214960983, COSV100052958; called by muse, mutect2, varscan2
- DLG5 | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs754115676, COSV64948821; called by muse, mutect2
- DLG5 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.876); catalogued as rs749558640, COSV100967253; called by muse, mutect2, varscan2
- DLGAP4 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV59424082; called by muse, mutect2, varscan2
- DLST | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753854732, COSV99471779; called by muse, mutect2, varscan2
- DMKN | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs373879312; called by mutect2, varscan2
- DNAH10 | c.1543G>A p.E515K (on ENST00000409039; = p.E454K on NM_207437.3) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs1445065172, COSV69003141; called by muse, mutect2, varscan2
- DNAH17 | c.11447A>C p.K3816T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV101101448; called by muse, mutect2, varscan2
- DNAH17 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as rs775758076, COSV101101451; called by muse, mutect2, varscan2
- DNAH17 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.578); catalogued as COSV101101453; called by muse, mutect2, varscan2
- DNAH3 | c.2209G>A p.V737M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.345); catalogued as rs752953355, COSV99764978; called by muse, mutect2, varscan2
- DNAH7 | c.9193C>T p.R3065W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs372195820; called by muse, mutect2, varscan2
- DNAH9 | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as rs757776336, COSV99304140, COSV99304908; called by muse, mutect2, varscan2
- DNAI4 | c.1982C>A p.A661D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1553211817, COSV100925259, COSV64023092; called by muse, mutect2, varscan2
- DNAJC3 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as rs1036875025, COSV100953275; called by muse, mutect2, varscan2
- DNMBP | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs201994777, COSV60626325; called by mutect2, varscan2
- DNMT1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.354); catalogued as COSV100531752, COSV100533157; called by muse, mutect2, varscan2
- DOCK1 | c.5020C>T p.P1674S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as rs575108104, COSV99726834; called by muse, mutect2, varscan2
- DOCK11 | c.5186G>A p.R1729H | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs1385641477, COSV99352902; called by muse, mutect2, varscan2
- DOCK8 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs373168547; called by mutect2, varscan2
- DRP2 | c.438G>A p.A146= | Splice Region (SNP) | VAF 13/30 reads (43%) | catalogued as rs372809310, COSV100871789, COSV100872007; called by muse, mutect2, varscan2
- DSCAM | c.4507G>A p.G1503S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs754031424, COSV68026604, COSV68034512; called by muse, mutect2, varscan2
- DSG3 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1268604594, COSV99933754; called by muse, mutect2
- DST | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs183558657, COSV56808337; called by muse, mutect2, varscan2
- DTX1 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs201380111, COSV57496091; called by muse, mutect2, varscan2
- DYRK1A | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV58292491; called by muse, mutect2
- EBF3 | c.1517C>T p.S506L (on ENST00000355311 / NM_001375392.1; = p.S497L on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs750469936, COSV100798977; called by muse, mutect2
- EDIL3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs757863733, COSV56879041; called by muse, mutect2, varscan2
- EFEMP1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370831953; called by muse, mutect2, varscan2
- EFTUD2 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1206259660, COSV68182843; called by muse, mutect2, varscan2
- EGR4 | c.940C>T p.L314F (on ENST00000545030; = p.L211F on NM_001965.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV101474207; called by muse, mutect2, varscan2
- EIF2AK3 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748318874, CM097402, COSV57545397; called by mutect2, varscan2
- EIF3D | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as rs371499563; called by muse, mutect2, varscan2
- ELFN2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs760548220, COSV68746931; called by muse, mutect2, varscan2
- ELN | c.832G>T p.G278* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99332240; called by muse, mutect2, varscan2
- EML4 | c.2306C>T p.T769M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs150527843; called by muse, mutect2, varscan2
- EMSY | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV100595396; called by muse, mutect2, varscan2
- ENPP3 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62954563; called by muse, mutect2, varscan2
- EP300 | c.4886C>T p.A1629V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54330195; called by muse, mutect2, varscan2
- EPPK1 | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782407539, COSV101599710; called by muse, mutect2
- EPS8L1 | c.1493C>T p.S498L (on ENST00000201647 / NM_133180.3; = p.S371L on NM_017729.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52380417; called by muse, mutect2, varscan2
- EPS8L2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs753332879, COSV100585310; called by muse, mutect2, varscan2
- ERBB3 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.782); catalogued as rs746806935, COSV99915785; called by mutect2, varscan2
- ERCC6 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs56397747, COSV63388105; called by mutect2, varscan2
- EXOC3L2 | c.2320C>A p.L774I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.298); catalogued as COSV99374450; called by muse, mutect2, varscan2
- EXOSC5 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99524424; called by muse, mutect2, varscan2
- EYA4 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs747223436, COSV100765189; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FAIM | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1243852478, COSV100623864; called by muse, mutect2, varscan2
- FAM171A1 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs377506137; called by muse, mutect2, varscan2
- FAM177A1 | c.631G>A p.V211I (on ENST00000382406 / NM_001289022.2; = p.V234I on NM_173607.5) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.825); catalogued as COSV99805673; called by muse, mutect2, varscan2
- FAM193A | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61190516; called by muse, mutect2, varscan2
- FAM214A | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs200481090; called by muse, mutect2
- FAM234A | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs968172651, COSV56996110; called by muse, mutect2, varscan2
- FAM83G | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as rs758694379, COSV58759958; called by muse, mutect2, varscan2
- FAM98A | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV99479034; called by muse, mutect2, varscan2
- FARP2 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs369372470; called by muse, mutect2, varscan2
- FASN | c.5207C>T p.T1736M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408119005, COSV60753588; called by muse, mutect2, varscan2
- FASN | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as rs199546508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT1 | c.4117G>A p.V1373I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772458984, COSV71676289; called by muse, mutect2, varscan2
- FBL | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99695154; called by muse, mutect2, varscan2
- FBLN1 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770235111, COSV99410052, COSV99410916; called by muse, mutect2, varscan2
- FBXO25 | c.373G>A p.V125M (on ENST00000382824 / NM_183421.2; = p.V58M on NM_012173.3) | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99366742; called by muse, mutect2
- FCGBP | c.10049G>A p.R3350Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as rs1270330427; called by muse, mutect2, varscan2
- FCGBP | c.6661G>A p.D2221N | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1209163607; called by muse, mutect2
- FCN1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765314208, COSV65661949; called by muse, mutect2, varscan2
- FGFR4 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201831200; called by mutect2, varscan2
- FHOD1 | c.2831G>A p.R944K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99263819; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FKBP1B | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs1030452126, COSV99272576; called by muse, mutect2, varscan2
- FLG | c.5440C>T p.R1814C | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as rs772552807, COSV100910509, COSV100910637; called by muse, mutect2, varscan2
- FLG | c.4993C>T p.Q1665* | Nonsense Mutation (SNP) | VAF 49/203 reads (24%) | catalogued as COSV100910510; called by muse, mutect2, varscan2
- FLG | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.155); catalogued as rs149884927, COSV64247011; called by muse, mutect2
- FLNC | c.3488C>T p.P1163L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs377489161, CM1512367, COSV100367631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs142392340; called by mutect2, varscan2
- FOXC2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100234095; called by muse, mutect2, varscan2
- FOXI1 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60389836; called by muse, mutect2, varscan2
- FOXRED2 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53398859; called by muse, mutect2
- FPGT | c.431del p.F144Sfs*14 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV63847471; called by mutect2, pindel, varscan2
- FPR2 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs765433312, COSV100389115; called by muse, mutect2, varscan2
- FPR2 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100389116; called by muse, mutect2
- FRMPD1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs779949389, COSV100899309; called by muse, mutect2, varscan2
- FSCN3 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.759); catalogued as rs202126167, COSV56170838, COSV99757028; called by muse, mutect2, varscan2
- FYN | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs376211530; called by muse, mutect2, varscan2
- GALK2 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100508602; called by muse, mutect2, varscan2
- GALNT14 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367671327; called by mutect2, varscan2
- GAPDHS | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147205628, COSV99722205; called by muse, mutect2, varscan2
- GAS2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.177); catalogued as COSV53408000; called by muse, mutect2, varscan2
- GAS6 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs767144171, COSV59849902; called by mutect2, varscan2
- GBX1 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99880738; called by muse, mutect2, varscan2
- GC | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs774755036, COSV56740398; called by muse, mutect2, varscan2
- GDF10 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as rs781793475; called by muse, mutect2, varscan2
- GDF2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs201507315, CM1512095; called by muse, mutect2, varscan2
- GDI1 | c.1101G>T p.E367D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99340847; called by muse, mutect2, varscan2
- GFRA2 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100151408; called by muse, mutect2, varscan2
- GGT5 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1231743112, COSV54068789; called by muse, mutect2, varscan2
- GGT7 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as rs201808310, COSV60540599; called by muse, mutect2, varscan2
- GIT1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56403318; called by muse, mutect2, varscan2
- GJA3 | c.140A>T p.D47V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99576262; called by muse, mutect2, varscan2
- GJC1 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.823); catalogued as rs1460737573, COSV100395122; called by muse, mutect2
- GK | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970772; called by muse, mutect2, varscan2
- GLB1L2 | c.1889G>A p.G630D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100335135; called by muse, mutect2, varscan2
- GLE1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100012331; called by muse, mutect2, varscan2
- GLI2 | c.1598G>A p.R533H (on ENST00000361492 / NM_001374353.1; = p.R550H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229340491, COSV58035376; called by muse, mutect2, varscan2
- GLRB | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV100029475; called by muse, mutect2
- GLS2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs751390826, COSV61738358; called by muse, mutect2, varscan2
- GLUL | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs776102116, COSV100091822; called by mutect2, varscan2
- GMEB2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as rs777285269, COSV56605652; called by mutect2, varscan2
- GMPR | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV99439757; called by muse, mutect2, varscan2
- GMPR2 | c.146C>T p.P49L (on ENST00000355299 / NM_001351022.2; = p.P67L on NM_016576.5) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99164592; called by muse, mutect2, varscan2
- GOLGA3 | c.3044C>T p.A1015V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.165); catalogued as rs567702653, COSV52633154; called by muse, mutect2
- GOLGA8G | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs1337358652; called by muse, mutect2
- GOLPH3 | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs1466667875, COSV99417007; called by muse, mutect2, varscan2
- GPANK1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1261272958, COSV100788966; called by mutect2, varscan2
- GPATCH8 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100132468; called by muse, mutect2, varscan2
- GPR108 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs369806355; called by muse, mutect2, varscan2
- GPR149 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67665860; called by muse, mutect2
- GPR15 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.123); catalogued as rs1300446215, COSV99423638; called by muse, mutect2, varscan2
- GPR158 | c.2043A>T p.E681D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892886; called by muse, mutect2
- GRAMD1B | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs901617580, COSV100454284; called by muse, mutect2, varscan2
- GRIA2 | c.30_32del p.L11del | In Frame Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs1299198234; called by pindel, varscan2
- GRIK1 | c.2750C>T p.T917I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as COSV100515886; called by muse, mutect2, varscan2
- GRK6 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs551864050, COSV100586831; called by muse, mutect2, varscan2
- GRM5 | c.3500C>T p.S1167F (on ENST00000305447 / NM_001143831.2; = p.S1135F on NM_000842.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100550243; called by muse, mutect2, varscan2
- GRM6 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as rs779188022, COSV51436948; called by mutect2, varscan2
- GRM7 | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387453915, COSV100735701; called by muse, mutect2, varscan2
- GSE1 | c.3008C>T p.P1003L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs148102403; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1554532942, COSV57032460; called by muse, mutect2, varscan2
- GTF3C1 | c.2062-1G>A p.X688_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100648968; called by muse, mutect2, varscan2
- H2AC13 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100704315; called by muse, mutect2, varscan2
- H2AP | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV100586898; called by muse, mutect2, varscan2
- H3C12 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.348); catalogued as COSV100377461, COSV58152091; called by muse, mutect2, varscan2
- HARS1 | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100297859; called by muse, mutect2, varscan2
- HAS3 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as rs369355805; called by muse, mutect2, varscan2
- HCFC1 | c.4444C>T p.R1482W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs782102190, COSV60077279; called by muse, mutect2, varscan2
- HDAC9 | c.1978C>T p.R660* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs758672820, COSV67774088; called by muse, mutect2, varscan2
- HDLBP | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as rs1420844409, COSV100189893; called by muse, mutect2, varscan2
- HEATR6 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99482110; called by muse, mutect2, varscan2
- HECTD4 | c.12647C>T p.T4216M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs1250322111, COSV101106725; called by muse, mutect2
- HERC2 | c.14177G>A p.R4726Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761534722, COSV55352331; called by muse, mutect2
- HGS | c.976-1G>A p.X326_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV100230209; called by muse, mutect2, varscan2
- HHATL | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as rs539401061, COSV55135537; called by muse, mutect2, varscan2
- HIVEP3 | c.1660del p.H554Tfs*20 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as rs1558087190; called by mutect2, pindel, varscan2
- HLA-G | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as rs759548979, COSV100826977; called by muse, mutect2, varscan2
- HLTF | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100026718; called by muse, mutect2, varscan2
- HLTF | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs527812739, COSV59503687; called by muse, mutect2, varscan2
- HMOX1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs903006597, COSV99330584; called by muse, mutect2, varscan2
- HOMER3 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV99650893; called by muse, mutect2, varscan2
- HOXB3 | c.803C>A p.P268H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as COSV99042268; called by muse, mutect2, varscan2
- HOXD3 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1217925935, COSV99979887; called by muse, mutect2, varscan2
- HP1BP3 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs968930016, COSV100391550, COSV56565253; called by muse, mutect2, varscan2
- HS3ST3A1 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs1453715850, COSV52377419; called by muse, mutect2
- HSD17B12 | c.614C>G p.T205S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.186); catalogued as COSV99550302; called by muse, mutect2
- HSPA13 | c.100A>T p.I34F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV99579873; called by muse, mutect2, varscan2
- HTR1A | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV60501281; called by muse, mutect2
- HTR1B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.012); catalogued as COSV64051085; called by muse, mutect2, varscan2
- HUWE1 | c.5339G>A p.R1780H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53355675; called by muse, mutect2, varscan2
- IGHG2 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs1297005778; called by muse, mutect2
- IGLV1-40 | c.206T>A p.I69N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs747413615; called by muse, mutect2, varscan2
- IGSF6 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs138907452; called by muse, varscan2
- IGSF8 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs1473037713, COSV100081517; called by muse, mutect2, varscan2
- IL1RAPL2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782435701, COSV100780736; called by muse, mutect2, varscan2
- ILK | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as rs1179732298, COSV100196109; called by muse, mutect2
- IMMT | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99607031; called by muse, mutect2, varscan2
- ING1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs766391738, COSV100311978, COSV58169128; called by muse, mutect2, varscan2
- INTS11 | c.1237G>T p.V413L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100028004; called by muse, mutect2, varscan2
- INTS13 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV99677151; called by muse, mutect2, varscan2
- IPO7 | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101121781, COSV65685068; called by muse, mutect2, varscan2
- IQCE | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs754176708, COSV58076363; called by muse, mutect2, varscan2
- IQGAP3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370931618; called by muse, mutect2, varscan2
- IRF8 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs769456462, COSV99236068; called by muse, mutect2, varscan2
- IRS4 | c.1076G>T p.R359M | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100929423; called by muse, mutect2, varscan2
- IRX5 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100315621; called by muse, mutect2, varscan2
- ISX | c.708del p.K236Nfs*69 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as COSV58088190; called by mutect2, pindel, varscan2
- ITGA10 | c.366G>T p.M122I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100994711; called by muse, mutect2
- ITGA6 | c.2362G>A p.V788I (on ENST00000442250; = p.V749I on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV99905052; called by muse, mutect2, varscan2
- ITGAE | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99560378; called by muse, mutect2, varscan2
- ITGB1BP2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752930291, COSV52139866; called by muse, mutect2, varscan2
- ITIH1 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs371375008, COSV99834939; called by muse, mutect2, varscan2
- ITIH4 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376550669; called by muse, mutect2, varscan2
- ITPR3 | c.1859G>A p.S620N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV100966925; called by mutect2, varscan2
- ITSN1 | c.4478C>T p.T1493M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs1040261538, COSV67157082; called by muse, mutect2, varscan2
- JAG2 | c.2249-1G>A p.X750_splice | Splice Site (SNP) | VAF 10/105 reads (10%) | catalogued as COSV100077907; called by muse, mutect2, varscan2
- JAKMIP3 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100058667; called by muse, mutect2, varscan2
- JSRP1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV99677594; called by muse, mutect2, varscan2
- JUNB | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV57058805; called by muse, mutect2, varscan2
- KBTBD6 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs770403753, COSV101068694; called by muse, mutect2, varscan2
- KCNA4 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); catalogued as rs375529159; called by muse, mutect2, varscan2
- KCNH7 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV100034104, COSV59782878; called by muse, mutect2, varscan2
- KCNQ1 | c.1870A>G p.T624A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99325731; called by mutect2, varscan2
- KCNQ3 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66464707; called by muse, mutect2, varscan2
- KDELR1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.08); catalogued as rs780757543, COSV58101721; called by muse, mutect2, varscan2
- KDM1B | c.1036G>A p.V346I (on ENST00000449850; = p.V214I on NM_153042.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs754264817, COSV52814176; called by muse, mutect2, varscan2
- KDM4B | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs766608517, COSV99345529; called by muse, mutect2, varscan2
- KDM5A | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as rs546854883, COSV66995097; called by muse, mutect2, varscan2
- KIAA0319 | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as rs756526138, COSV65501093; called by muse, mutect2, varscan2
- KIAA0895L | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs752315601, COSV51782673, COSV99220377; called by muse, mutect2, varscan2
- KIAA1210 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV68180629, COSV68181153; called by muse, mutect2, varscan2
- KIAA1549L | c.3307C>T p.R1103W (on ENST00000321505; = p.R1400W on NM_012194.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747515119, COSV55769669; called by muse, mutect2, varscan2
- KIF2A | c.1994C>G p.A665G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV101136255; called by muse, mutect2
- KIF3C | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1186222505, COSV53101449; called by muse, mutect2, varscan2
- KLF16 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99170512; called by muse, mutect2, varscan2
- KLHL14 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV100808634; called by muse, mutect2
- KLHL32 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs753639648, COSV100987143, COSV100987309; called by muse, mutect2, varscan2
- KLHL36 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1369241402, COSV50717988; called by muse, mutect2, varscan2
- KLK12 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as rs1440261608, COSV51577406; called by muse, mutect2, varscan2
- KLK15 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV56827425; called by muse, mutect2, varscan2
- KLK9 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs942944016, COSV51591599; called by muse, mutect2, varscan2
- KMT2A | c.10030G>A p.V3344I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs781850448, COSV63291584; called by muse, mutect2, varscan2
- KMT2D | c.11456G>A p.G3819D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs527356550, CD156341, COSV99977578; called by muse, mutect2, varscan2
- KMT2D | c.9563C>T p.T3188M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs762206028, COSV99977582; called by mutect2, varscan2
- KMT2E | c.2978A>C p.Q993P | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99995796; called by muse, mutect2, varscan2
- KPNA3 | c.771+1G>A p.X257_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55507483; called by muse, mutect2, varscan2
- KRT33B | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.487); catalogued as rs774682769, COSV99290473; called by muse, mutect2, varscan2
- KRTAP12-3 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs782173625, COSV100551908; called by muse, mutect2
- LAMA1 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs372203316, COSV101054895; called by muse, mutect2, varscan2
- LAMA2 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101370045; called by muse, mutect2, varscan2
- LAMA4 | c.2900C>T p.S967L (on ENST00000230538 / NM_001105206.3; = p.S960L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs782682713, COSV57901390; called by muse, mutect2, varscan2
- LAMA4 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs148801194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs745957879, COSV59732108; called by muse, mutect2, varscan2
- LARP1B | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs776676378, COSV99217772; called by muse, mutect2, varscan2
- LATS1 | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99485283; called by muse, mutect2, varscan2
- LDHC | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs771264967, COSV99772303; called by muse, mutect2, varscan2
- LDHD | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.101); catalogued as rs746841665, COSV100096709; called by mutect2, varscan2
- LHX3 | c.253C>T p.R85C (on ENST00000371748 / NM_178138.6; = p.R90C on NM_014564.5) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV65583666; called by muse, mutect2
- LIG3 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145709942; called by muse, mutect2, varscan2
- LILRA2 | c.33C>T p.L11= | Splice Region (SNP) | VAF 37/249 reads (15%) | catalogued as rs759331053, COSV99252747; called by muse, mutect2, varscan2
- LILRB3 | c.1685G>A p.S562N (on ENST00000346401; = p.S550N on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as COSV99557085; called by muse, mutect2
- LINC02210-CRHR1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs564745730, COSV53277908; called by muse, mutect2, varscan2
- LMBRD1 | c.947G>T p.W316L (on ENST00000649011; = p.W294L on NM_018368.4) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.999); catalogued as COSV100992449; called by muse, mutect2, varscan2
- LMTK2 | c.3235G>A p.G1079S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs200437650, COSV99806014; called by muse, mutect2, varscan2
- LMTK2 | c.4351C>G p.P1451A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99806017; called by muse, mutect2, varscan2
- LONP1 | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs754884886, COSV100638517, COSV99052283; called by muse, mutect2, varscan2
- LONRF2 | c.2138A>G p.Q713R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101110855; called by muse, mutect2, varscan2
- LPCAT1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs377578537; called by muse, mutect2
- LRIG1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs373112316; called by mutect2, varscan2
- LRP1 | c.6110G>A p.R2037Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs145430854, COSV54508613; called by muse, mutect2, varscan2
- LRP10 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100612279; called by mutect2, varscan2
- LRP1B | c.7730G>A p.C2577Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101249657; called by muse, mutect2, varscan2
- LRP2 | c.12296-1G>T p.X4099_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as COSV55538744; called by muse, mutect2, varscan2
- LRPPRC | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs142097048; ClinVar: uncertain significance; called by mutect2, varscan2
- LRPPRC | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs372127413, COSV53238316; called by mutect2, varscan2
- LRRC14B | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.052); catalogued as rs372911383; called by muse, mutect2, varscan2
- LRRC15 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs888813435, COSV61649445; called by muse, mutect2
- LRRC15 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs774509554, COSV100752537; called by mutect2, varscan2
- LRRC37A3 | c.4591C>T p.Q1531* | Nonsense Mutation (SNP) | VAF 51/206 reads (25%) | catalogued as COSV100140833; called by muse, mutect2, varscan2
- LRRC37B | c.1150C>A p.L384M | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV100496023; called by muse, mutect2, varscan2
- LRRC55 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs749027630, COSV101546699; called by mutect2, varscan2
- LRRFIP1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541856021, COSV99790377; called by muse, mutect2, varscan2
- LTB4R | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs150532344, COSV99350473; called by muse, mutect2, varscan2
- LY75 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs113288676, COSV55108228, COSV55114364; called by muse, mutect2, varscan2
- LY9 | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99626196; called by muse, mutect2
- LYSMD4 | c.175G>A p.G59S (on ENST00000409796 / NM_001284417.2; = p.A29= on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100230502, COSV100230655; called by muse, mutect2
- M6PR | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780103335, COSV99134088; called by mutect2, varscan2
- MAG | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.791); catalogued as rs1208575137, COSV62698865; called by muse, mutect2, varscan2
- MAGEA8 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as COSV99674401; called by muse, mutect2
- MAGEA8 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1557371039, COSV54064054; called by muse, mutect2, varscan2
- MAGI1 | c.3451C>T p.R1151C (on ENST00000402939 / NM_001033057.2; = p.R1180C on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141617754; called by muse, mutect2, varscan2
- MAMDC4 | c.2044G>A p.G682S (on ENST00000445819; = p.G603S on NM_206920.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as rs202047991, COSV100439815; called by muse, mutect2, varscan2
- MAML2 | c.2954G>A p.R985H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs367748029; called by muse, mutect2, varscan2
- MAP6 | c.2033G>T p.G678V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100496455; called by muse, mutect2, varscan2
- MAPKAPK5 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341844200, COSV101612863; called by muse, mutect2, varscan2
- MAST4 | c.3208C>T p.R1070* (on ENST00000403625 / NM_001164664.2; = p.R881* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as rs761762651, COSV55143526; called by mutect2, varscan2
- MAST4 | c.6740C>T p.P2247L (on ENST00000403625 / NM_001164664.2; = p.P2058L on NM_015183.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs770880240, COSV99842866; called by muse, mutect2, varscan2
- MBD3 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs1260547532, COSV99336843; called by muse, mutect2
- MCAT | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201441121, COSV51793238; called by muse, mutect2, varscan2
- MCTP2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs143853824; called by muse, mutect2
- MDN1 | c.15347G>A p.R5116H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs761471330, COSV65518075; called by muse, mutect2, varscan2
- MED12 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as COSV100376117; called by muse, mutect2
- MED12L | c.5453G>A p.G1818D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1271687337, COSV99851545; called by muse, mutect2, varscan2
- MED23 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100644759; called by muse, mutect2
- MEGF8 | c.5597G>A p.R1866H (on ENST00000251268 / NM_001271938.2; = p.R1799H on NM_001410.3) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.95); catalogued as rs1002807575, COSV52074156; called by muse, mutect2, varscan2
- MEI1 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs767158440, COSV100299601; called by mutect2, varscan2
- MEN1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV56340023; called by muse, mutect2
- METRNL | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV100193595; called by muse, mutect2, varscan2
- MIA2 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99696617; called by muse, mutect2, varscan2
- MMAA | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs374622922; called by muse, mutect2, varscan2
- MMP15 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs754933485, COSV99539262; called by mutect2, varscan2
- MN1 | c.3731C>T p.T1244M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1160944052, COSV100179651; called by muse, mutect2
- MORC2 | c.1667C>T p.T556M (on ENST00000397641 / NM_001303256.3; = p.T494M on NM_014941.3) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs776665575, COSV53197804; called by muse, mutect2, varscan2
- MPDZ | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777601165, COSV59938151; called by muse, mutect2, varscan2
- MROH1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs771148811, COSV100395545, COSV58189920; called by muse, mutect2, varscan2
- MSL3 | c.739G>A p.A247T (on ENST00000312196 / NM_078629.4; = p.A81T on NM_006800.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as rs1183184259, COSV100384544; called by muse, mutect2, varscan2
- MSR1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs940157425, COSV100026548; called by muse, mutect2
- MTPAP | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs771523018, COSV53932867, COSV99553818; called by muse, mutect2, varscan2
- MTUS1 | c.901G>C p.V301L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as COSV50561674, COSV50563155; called by muse, mutect2, varscan2
- MTUS2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs377003171, COSV54994077; called by mutect2, varscan2
- MUC5AC | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.9); catalogued as rs751157368, COSV100650510; called by mutect2, varscan2
- MYBBP1A | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs201294033; called by mutect2, varscan2
- MYBL2 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99406012; called by muse, mutect2, varscan2
- MYCBP2 | c.7316C>T p.A2439V (on ENST00000357337; = p.A2477V on NM_015057.5) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1409620221, COSV100629228; called by muse, mutect2, varscan2
- MYCN | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55260999; called by muse, mutect2
- MYH10 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1470703280, COSV52609362; called by muse, mutect2, varscan2
- MYH14 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768787467, COSV99221754; called by muse, mutect2, varscan2
- MYH7 | c.1840C>A p.L614I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.303); catalogued as COSV100805696; called by muse, mutect2, varscan2
- MYH7B | c.4634C>T p.T1545M | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs766259714, COSV99327803; called by muse, mutect2, varscan2
- MYL9 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs766224371, COSV99640934; called by mutect2, varscan2
- MYO1F | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs201646155, COSV57791852; called by mutect2, varscan2
- MYO7A | c.3836C>T p.T1279M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766245260, COSV101289001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as COSV68279828; called by muse, mutect2
- MYOC | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1022182938, COSV50674211; called by muse, mutect2
- MYOM3 | c.3934G>T p.A1312S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV100141546; called by muse, mutect2
- MYPN | c.1461A>G p.K487= | Splice Region (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100589533; called by mutect2, varscan2
- MZT2B | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs773776345, COSV99919632; called by muse, mutect2, varscan2
- NADK | c.1308_1309insAAG p.F436_E437insK | In Frame Ins (INS) | VAF 11/62 reads (18%) | catalogued as COSV100410657, COSV58272668; called by mutect2, varscan2
- NAV1 | c.3148C>T p.R1050* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as rs777661769, COSV99818219; called by muse, mutect2, varscan2
- NAV1 | c.3659C>T p.S1220F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99818220; called by muse, mutect2
- NDOR1 | c.1244G>A p.R415Q (on ENST00000371521 / NM_001144026.3; = p.R408Q on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.083); catalogued as rs140457258; called by muse, mutect2, varscan2
- NDUFA13 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.883); catalogued as rs759639695, COSV99388902; called by muse, mutect2, varscan2
- NDUFS8 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs754342395, COSV50290012; called by muse, mutect2, varscan2
- NEGR1 | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100160963; called by muse, mutect2, varscan2
- NEUROG3 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.376); catalogued as COSV99653430; called by muse, mutect2, varscan2
- NFASC | c.1261G>A p.A421T (on ENST00000339876 / NM_001378329.1; = p.A432T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs775719693, COSV58380118; called by muse, mutect2, varscan2
- NFKB1 | c.2720C>T p.S907L (on ENST00000394820 / NM_001382627.1; = p.S908L on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs369577304; called by muse, mutect2, varscan2
- NINJ1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs202187907; called by muse, mutect2, varscan2
- NINL | c.1391A>G p.Q464R | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99624589; called by muse, mutect2
- NISCH | c.4105C>T p.R1369C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs114899589; called by muse, mutect2, varscan2
- NKD1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs757689418, COSV99194006; called by muse, mutect2, varscan2
- NKIRAS1 | c.333del p.E112Rfs*2 | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | catalogued as rs960308270; called by mutect2, pindel, varscan2
- NKPD1 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100521452; called by mutect2, varscan2
- NMT2 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs1284076209, COSV100975462; called by muse, mutect2, varscan2
- NOCT | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1320469628, COSV99763729; called by muse, mutect2, varscan2
- NOD1 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs754320439, COSV56115671; called by mutect2, varscan2
- NOP2 | c.964C>T p.R322* (on ENST00000322166 / NM_001258308.2; = p.R318* on NM_006170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100444636; called by muse, mutect2, varscan2
- NOP53 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs779428264, COSV99884110; called by muse, mutect2, varscan2
- NOS1 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100500028; called by muse, mutect2, varscan2
- NOS3 | c.3460C>T p.R1154C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1399853333, COSV52489539; called by muse, mutect2
- NOTCH1 | c.2755G>A p.G919R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478316908, COSV53063387, COSV53078294, COSV99486952; called by muse, mutect2
- NOTCH3 | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs370233852; ClinVar: likely benign; called by mutect2, varscan2
- NOVA1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.81); catalogued as COSV99946509; called by muse, mutect2, varscan2
- NPAP1 | c.3188G>A p.G1063D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.685); catalogued as COSV100274785; called by muse, mutect2, varscan2
- NPAS1 | c.960C>T p.S320= | Splice Region (SNP) | VAF 9/92 reads (10%) | catalogued as COSV101463920; called by muse, mutect2
- NPFFR2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs764733391, COSV58150066; called by muse, mutect2, varscan2
- NPHS1 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs144203682; ClinVar: uncertain significance; called by mutect2, varscan2
- NPHS1 | c.2702G>A p.S901N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as rs768225356, COSV100799606; called by muse, mutect2, varscan2
- NPPA | c.29G>C p.S10T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV100411582; called by muse, mutect2, varscan2
- NPSR1 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs767507530, COSV100705740; called by mutect2, varscan2
- NR2C2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); catalogued as rs764193834, COSV60144852; called by muse, mutect2, varscan2
- NR2F1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs776020140, COSV59067477, COSV59068187; called by muse, mutect2, varscan2
- NRG1 | c.125G>A p.G42D (on ENST00000523534; = p.G189D on NM_013962.2) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs992418789, COSV101584744; called by muse, mutect2
- NRXN1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.89); catalogued as rs761279630, COSV58450781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSRP1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs770079774, COSV99898176; called by muse, mutect2, varscan2
- NTF4 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs200675509, COSV56825550; called by muse, mutect2, varscan2
- NTHL1 | c.193C>T p.R65C (on ENST00000219066; = p.R57C on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs767591879, COSV54593289; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NTPCR | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.204); catalogued as COSV100786674; called by muse, mutect2, varscan2
- NUCB1 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99617709; called by mutect2, varscan2
- NUP155 | c.3634T>C p.S1212P (on ENST00000231498 / NM_153485.3; = p.S1153P on NM_004298.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.845); catalogued as COSV99192232; called by muse, mutect2, varscan2
- NUP188 | c.2186G>T p.R729M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101001188; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs760869296; called by mutect2, varscan2
- NUP58 | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 13/76 reads (17%) | catalogued as COSV101098562; called by muse, mutect2, varscan2
- OGFOD2 | c.235G>C p.A79P (on ENST00000228922 / NM_001304833.1; = p.A19P on NM_024623.3) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV99965539; called by muse, mutect2, varscan2
- OGT | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs867312215, COSV101035167, COSV104424951; called by muse, mutect2
- ONECUT1 | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100009032; called by muse, mutect2, varscan2
- OPRD1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.235); catalogued as rs766428641, COSV99330064; called by muse, mutect2, varscan2
- OR13A1 | c.568A>G p.N190D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100980971; called by muse, mutect2, varscan2
- OR1F1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs751283450, COSV100484508, COSV58961993; called by muse, mutect2
- OR52L1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs754435262, COSV100176022; called by muse, mutect2, varscan2
- OR5T1 | c.98T>C p.F33S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs761096949, COSV100478722, COSV100478941; called by muse, mutect2, varscan2
- OR6B1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766092045, COSV68770201; called by muse, mutect2, varscan2
- OSBPL2 | c.476C>T p.T159M (on ENST00000313733 / NM_144498.4; = p.T147M on NM_014835.4) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100569134; called by muse, mutect2
- OSBPL3 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1462910997, COSV57655851; called by muse, mutect2, varscan2
- OSBPL7 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs761987869, COSV99136527; called by muse, mutect2, varscan2
- OTUD4 | c.1136C>A p.P379H (on ENST00000447906 / NM_001366057.1; = p.P314H on NM_001102653.1) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101485880; called by muse, mutect2, varscan2
- OXER1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs547163136, COSV54313917; called by muse, mutect2, varscan2
- P2RX3 | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99628354; called by muse, mutect2
- P3H3 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368711010; called by muse, mutect2, varscan2
- P4HB | c.1485G>T p.M495I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100515740; called by muse, mutect2, varscan2
- PACS1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100269549; called by muse, mutect2, varscan2
- PAN3 | c.811A>G p.N271D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.828); catalogued as rs1353841883, COSV101111090; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBX1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as rs1349939044, COSV100522045; called by muse, mutect2, varscan2
- PCDH9 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60590566; called by muse, mutect2, varscan2
- PCDH9 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs376583062, COSV60546646; called by mutect2, varscan2
- PCDHA2 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); catalogued as COSV65365499; called by muse, mutect2, varscan2
- PCDHB10 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.013); catalogued as rs371890899; called by muse, mutect2, varscan2
- PCDHB15 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV51424178; called by muse, mutect2, varscan2
- PCDHB2 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); catalogued as rs782083757, COSV50595165; called by muse, mutect2
- PCDHB3 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV50577410; called by muse, mutect2, varscan2
- PCDHB3 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.089); catalogued as rs782039280, COSV99164174; called by muse, mutect2, varscan2
- PCDHB4 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99521837; called by muse, mutect2
- PCDHB8 | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs782662625, COSV99175661; called by muse, mutect2
- PCDHGA11 | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53934490; called by muse, mutect2, varscan2
- PCF11 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100017778; called by muse, mutect2
- PDE11A | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV53690745; called by muse, mutect2, varscan2
- PDE9A | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs201357375, COSV52324362; called by mutect2, varscan2
- PDGFRA | c.3199A>G p.I1067V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.12); catalogued as rs1321102144, COSV99955455; called by muse, mutect2, varscan2
- PDK1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.154); catalogued as rs373351437; called by muse, mutect2, varscan2
- PEX6 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as COSV99769495; called by muse, mutect2, varscan2
- PHIP | c.5197G>A p.A1733T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99243414; called by muse, mutect2, varscan2
- PHYH | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99538008; called by mutect2, varscan2
- PI4KA | c.4811C>T p.P1604L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs754586130, COSV99744319; called by muse, mutect2, varscan2
- PIK3AP1 | c.1717T>C p.S573P | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.341); catalogued as COSV100225509; called by muse, mutect2, varscan2
- PIK3C3 | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100010315; called by muse, mutect2, varscan2
- PIK3C3 | c.2366dup p.T790Hfs*4 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | catalogued as rs1247541427; called by mutect2, pindel, varscan2
- PIP4P1 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99164444; called by muse, mutect2, varscan2
- PITPNM2 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1432266501, COSV54905248, COSV99758301; called by muse, mutect2, varscan2
- PITPNM2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99758304; called by muse, mutect2, varscan2
- PKD1 | c.3587C>T p.T1196M | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs570064884, COSV99237156; called by muse, mutect2, varscan2
- PKD1L2 | c.2558C>T p.T853M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as rs574634034, COSV55171173, COSV55172355; called by muse, mutect2, varscan2
- PKHD1L1 | c.4937C>T p.T1646M | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs750284786, COSV101005390; called by muse, mutect2, varscan2
- PLA2G4A | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100820370; called by muse, mutect2, varscan2
- PLA2G4C | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769048180, COSV100843834; called by muse, mutect2, varscan2
- PLAC8 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as COSV100274436; called by muse, mutect2, varscan2
- PLAU | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs370557565; called by muse, mutect2, varscan2
- PLCB3 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99657097; called by muse, mutect2, varscan2
- PLD2 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as rs148063814; called by mutect2, varscan2
- PLEC | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781991899, COSV100510685; called by muse, mutect2, varscan2
- PLEKHA5 | c.1183G>T p.G395W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); catalogued as COSV100164228, COSV54712145; called by muse, mutect2, varscan2
- PLEKHG3 | c.2680C>T p.Q894* (on ENST00000394691; = p.Q950* on NM_001308147.2) | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99906254; called by muse, mutect2, varscan2
- PLPPR4 | c.2275C>T p.R759W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs998231690, COSV64564142, COSV64565285; called by muse, mutect2, varscan2
- PLVAP | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99391481; called by mutect2, varscan2
- PLXNA2 | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs371995694; called by mutect2, varscan2
- PLXNA2 | c.1544C>T p.T515M | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.501); catalogued as rs367700351, COSV65444236; called by muse, mutect2, varscan2
- PLXNA3 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1349992966, COSV100859803; called by muse, mutect2, varscan2
- PLXNA4 | c.4177G>A p.V1393M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs757554246, COSV58114031; called by muse, mutect2, varscan2
- PLXND1 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs765202904, COSV60714970; called by muse, mutect2, varscan2
- PNPLA4 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs375161440, COSV66854629; called by muse, varscan2
- POLA1 | c.4381A>G p.K1461E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as COSV100985011; called by muse, mutect2
- POLD2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs753677894, COSV56262795, COSV56264327; called by muse, mutect2, varscan2
- POU2AF1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67577201; called by muse, mutect2, varscan2
- POU4F2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs751800890, COSV99850272; called by muse, mutect2, varscan2
- POU4F3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM127918, COSV100046827, COSV100046948; called by muse, mutect2, varscan2
- PPM1A | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as rs1315212157, COSV100348690; called by muse, mutect2, varscan2
- PPP2R3B | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101065495; called by muse, mutect2, varscan2
- PPP6R2 | c.2561del p.P854Rfs*23 (on ENST00000216061 / NM_001365836.1; = p.P820Rfs*23 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as COSV53291064; called by mutect2, pindel, varscan2
- PQBP1 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV99504045; called by muse, mutect2, varscan2
- PQBP1 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1557041855, COSV99504047; called by muse, mutect2, varscan2
- PRELID1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100293451; called by muse, mutect2, varscan2
- PRICKLE1 | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308626806, COSV61542850; called by muse, mutect2, varscan2
- PRKAR1B | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs144462255; called by muse, mutect2, varscan2
- PRKD1 | c.1651G>T p.G551C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV100119308; called by muse, mutect2, varscan2
- PRKD2 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1213734409, COSV52187082; called by muse, mutect2, varscan2
- PROCA1 | c.487C>T p.L163F (on ENST00000439862 / NM_001366301.1; = p.L135F on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV99972520; called by muse, mutect2, varscan2
- PROKR2 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54088415, COSV99449845; called by muse, mutect2, varscan2
- PROSER3 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99994450; called by muse, mutect2
- PRPF3 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.072); catalogued as rs375363471; called by muse, mutect2, varscan2
- PRRT1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV99278213; called by muse, mutect2
- PSMB5 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs1043324810, COSV100557262; called by muse, mutect2
- PSME4 | c.1780C>T p.L594F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV101122226; called by muse, mutect2, varscan2
- PSORS1C2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs751039996, COSV99455942; called by muse, mutect2, varscan2
- PTPN4 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771281366, COSV99749559; called by muse, mutect2, varscan2
- PTPRB | c.2905G>A p.G969R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758312833, COSV104371426, COSV54250416, COSV99715814; called by muse, mutect2, varscan2
- PTPRS | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1237159914, COSV53613755; called by muse, mutect2, varscan2
- PTPRU | c.2600C>T p.T867M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs146215972; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | catalogued as rs772722517, COSV99560265; called by mutect2, pindel, varscan2
- PYGO2 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs758189275, COSV100868842; called by muse, mutect2, varscan2
- QRICH2 | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.36); catalogued as rs779417734, COSV99428800; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs561703908, COSV99241679; called by mutect2, varscan2
- RABL2B | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1262252948, COSV100711447; called by muse, mutect2, varscan2
- RAD54L2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.07); catalogued as rs1377904886, COSV56577385, COSV99620734; called by muse, mutect2
- RALGPS1 | c.1446+1G>A p.X482_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99400825; called by muse, mutect2, varscan2
- RAN | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV99619600; called by muse, mutect2, varscan2
- RARA | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.873); catalogued as COSV54195979; called by mutect2, varscan2
- RASAL2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.164); catalogued as COSV100862372; called by muse, mutect2
- RASGRP1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1407319895, COSV100171735; called by muse, mutect2, varscan2
- RBL2 | c.2384C>T p.T795I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as rs1455069047, COSV100043301; called by muse, mutect2, varscan2
- RBM44 | c.940C>T p.R314W (on ENST00000611254; = p.R948W on NM_001080504.2) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs372136649; called by muse, mutect2, varscan2
- RBP3 | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200537174; called by mutect2, varscan2
- REC114 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100461067; called by muse, mutect2, varscan2
- RECQL4 | c.2997G>T p.E999D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs902652277, COSV100020255; called by muse, mutect2, varscan2
- RELA | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58014798; called by muse, mutect2, varscan2
- REV1 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs758562897, COSV51482793, COSV51489060; called by muse, mutect2, varscan2
- REV3L | c.9230G>A p.R3077H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs201740580, COSV62617975; called by muse, mutect2, varscan2
- REX1BD | c.533+2T>C p.X178_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100678957; called by muse, mutect2, varscan2
- RFC5 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57477664, COSV57478901; called by muse, mutect2, varscan2
- RFX1 | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99585789; called by muse, mutect2
- RFX3 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as rs745514707, COSV56525967; called by mutect2, varscan2
- RGMA | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs754991211, COSV100224108; called by mutect2, varscan2
- RGS7 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773920063, COSV100464718; called by mutect2, varscan2
- RHBDF1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as rs1190170318, COSV51954748; called by muse, mutect2
- RIN3 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs373028854; called by muse, mutect2, varscan2
- RNF214 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56120437; called by muse, mutect2, varscan2
- RNFT2 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.058); catalogued as COSV99985011; called by muse, mutect2, varscan2
- ROCK1 | c.2561C>G p.T854R | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.414); catalogued as COSV101296237; called by muse, mutect2
- RPRD1B | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100987128; called by muse, mutect2, varscan2
- RPRD2 | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs759447769, COSV64818971; called by muse, mutect2, varscan2
- RPS6KA2 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV55818538; called by muse, mutect2, varscan2
- RPS6KA5 | c.2160+1G>A p.X720_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as rs1309003303, COSV100002072; called by muse, mutect2, varscan2
- RRAS | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99881961; called by muse, mutect2, varscan2
- RSF1 | c.489C>G p.Y163* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100406884; called by muse, mutect2, varscan2
- RTEL1 | c.2218C>A p.H740N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV100541583; called by muse, mutect2, varscan2
- RTL9 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.088); catalogued as rs771768405, COSV101511620; called by muse, mutect2, varscan2
- RUFY4 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as rs760520417, COSV60250370; called by muse, mutect2, varscan2
- RUSF1 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs150175927; called by mutect2, varscan2
- RXFP4 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754825959, COSV100562676; called by muse, mutect2, varscan2
- RYR3 | c.2164G>A p.G722S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV101212005; called by muse, mutect2, varscan2
- S1PR1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs11542632, COSV100541474; called by mutect2, varscan2
- SALL1 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as COSV99171558; called by muse, mutect2, varscan2
- SALL3 | c.3619G>A p.V1207I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.267); catalogued as rs367585625; called by muse, mutect2, varscan2
- SAMM50 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100601237; called by muse, mutect2, varscan2
- SAP130 | c.1466del p.L489Cfs*48 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as rs1198584290; called by mutect2, pindel, varscan2
- SCAF1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as COSV100862051; called by muse, mutect2
- SCN11A | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as rs747645678, COSV56569878; called by muse, mutect2, varscan2
- SCN4A | c.5309G>T p.G1770V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV101438317; called by muse, mutect2, varscan2
- SCUBE1 | c.1848G>T p.Q616H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100682852, COSV62611577; called by muse, mutect2, varscan2
- SEMA3A | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs553661856, COSV54881986; called by muse, mutect2, varscan2
- SEMA4D | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100357935; called by muse, mutect2, varscan2
- SEMA5B | c.3080C>T p.T1027I | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV52108300; called by muse, mutect2
680 further variants in this file (270 protein-altering or splice-affecting, 379 silent, 31 other) are not listed here.
